TCGA case TCGA-24-1560 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/afd92922-b8dc-48bd-a9c0-bc8d95855eb7

Demographics
Sex at birth: female; Race: white; Age at index: 51 years; Vital status: Dead; Days to death: 1,341 days (3.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.1 years (18,671 days); Year of diagnosis: 1999; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G4; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 117 days; Number of cycles: 6; Treatment dose: 4,620 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 117 days; Number of cycles: 6; Treatment dose: 1,620 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 398 days (1.1 years); Days to treatment end: 481 days (1.3 years); Number of cycles: 5; Treatment dose: 48 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Amifostine; Initial disease status: Progressive Disease; Days to treatment start: 509 days (1.4 years); Days to treatment end: 614 days (1.7 years); Number of cycles: 6; Treatment dose: 7,220 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 509 days (1.4 years); Days to treatment end: 614 days (1.7 years); Number of cycles: 6; Treatment dose: 3,100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 509 days (1.4 years); Days to treatment end: 614 days (1.7 years); Number of cycles: 6; Treatment dose: 1,730 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 635 days (1.7 years); Days to treatment end: 726 days (2.0 years); Number of cycles: 3; Treatment dose: 15,000 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 635 days (1.7 years); Days to treatment end: 726 days (2.0 years); Number of cycles: 3; Treatment dose: 200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 757 days (2.1 years); Days to treatment end: 901 days (2.5 years); Number of cycles: 6; Treatment dose: 2,875 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Days to treatment start: 757 days (2.1 years); Days to treatment end: 901 days (2.5 years); Number of cycles: 6; Treatment dose: 4,650 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 931 days (2.5 years); Days to treatment end: 1,015 days (2.8 years); Number of cycles: 5; Treatment dose: 210,000 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,043 days (2.9 years); Days to treatment end: 1,189 days (3.3 years); Number of cycles: 5; Treatment dose: 2,730 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,216 days (3.3 years); Days to treatment end: 1,258 days (3.4 years); Number of cycles: 3; Treatment dose: 1,640 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 51.5 years (18,814 days); Days to diagnosis: 143 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 143 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 143 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,341 days (3.7 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1560-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-24-1560-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 2.
  Slide TCGA-24-1560-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 2.
- Sample TCGA-24-1560-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 4: Pharmaceutical therapy drug name: Gemzar.
- Drug treatment 6: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 8: Pharmaceutical therapy drug name: Amitostin; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Etopside.
- Drug treatment 12: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 13: Pharmaceutical therapy drug name: Xeloda; Therapy regimen: Progression.
- Drug treatment 13, Route of administrations: Route of administration: PO.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,341 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,341 days; disease-free interval: event (new tumor event after initially disease-free), 143 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 143 days.
